Surgical pathology report (de-identified scan), TCGA case TCGA-55-A48Z, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A48Z-01A (Primary Tumor).

[page 1 of 2]
Sex
D.O.B.
MRN #
Ref Phy

PHYSICIAN INFORMATION

SPECIMEN INFORMATION

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Lymph node, level 9 right, dissection:
One benign lymph node (0/1).
- B. Lymph node, level 11, dissection:
Metastatic adenocarcinoma involving one of one lymph node (1/1).
- C. Lymph nodes, level 10, dissection:
Metastatic adenocarcinoma involving four of four lymph nodes (4/4).
- D. Lymph node, suprapulmonary vein, dissection:
Metastatic adenocarcinoma involving one of one lymph node (1/1).
- E. Lymph nodes, left level 7, dissection:
Metastatic adenocarcinoma involving four of four lymph nodes (4/4).

F. Right lung, pneumonectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Poorly differentiated with solid, micropapillary, and papillary architecture.
3. Tumor site: Right upper lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 2 cm in greatest dimension.
6. Visceral pleural invasion: Not identified (confirmed by elastic stain).
7. Lymphovascular space invasion: Present.
8. Tumor extension: Tumor is confined to the lung.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 7.2 cm.
2. Tumor distance from pleural surface: Less than 1 mm.

Lymph Node Status:

1. Total number of lymph nodes received: 1.
2. Total number of lymph nodes containing metastatic carcinoma: 1.

Other:

1. Other significant findings: The background lung shows mild respiratory bronchiolitis.
2. pTNM stage: pT1a N3 MX (see other parts).

G. Lymph nodes, level 4, dissection:

Metastatic adenocarcinoma involving three of eleven lymph nodes (3/11).
Hyalinized granulomas, AFB and GMS stains are negative for acid-fast and fungal microorganisms.

ICD-O-3

Adenocarcinoma with mixed subtypes

8255/3

Site = lung, upper lobe

9-11-12
RD

C34.1

Electronic Signature:

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: with right upper lobe lung cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Level 9 lymph node right
- B. Level 11 lymph node
- C. Level 10 lymph node
- D. Suprapulmonary vein lymph node
- E. Left level 7 lymph node
- F. Right lung
- G. Level 4 lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

- A. The first container A is received in formalin labeled with the patient's name 'level 9 right lymph node.' The specimen consists of a brown-tan nodule consistent with lymph node that measures 0.5 x 0.4 x 0.2 cm. The specimen is entirely submitted in a single cassette
- B. The second container B is received in formalin labeled 'level 11 lymph node.' The specimen consists of a brown-tan nodule consistent with lymph node that measures 1.0 x 0.5 x 0.5 cm. The lymph node is bisected, entirely submitted in a single cassette labeled
- C. The third container C is received in formalin labeled with the patient's name 'level 10 lymph node.' The specimen consists of four brown-tan nodules, possible lymph nodes 0.2 to 0.7 cm in greatest dimension. The largest lymph node is bisected and the specimen is entirely submitted in a single cassette
- D. The fourth container D is received in formalin labeled with the patient's name 'superior pulmonary vein lymph node.' The specimen consists of two brown-tan nodules consistent with lymph nodes that measure 0.3 x 0.2 x 0.2 and 0.6 x 0.4 x 0.2 cm. The specimen is entirely submitted in a single cassette labeled
- E. The fifth container E is received in formalin labeled with the patient's name 'level 7 lymph node.' The specimen consists of two pieces of brown-tan soft tissue measuring in aggregate 3.5 x 3.0 x 1.0 cm. On sectioning, there are four brown-tan nodules consistent with probable lymph nodes that measure from 0.9 to 1.5 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: two probable nodes each bisected in block 1; one probable node bisected in block 2; one probable node bisected in blocks 3 and 4.
- F. The sixth container F is received in formalin labeled with the patient's name 'right lung.' The specimen consists of right pneumonectomy specimen that measures 19.0 x 14.5 x 6.5 cm and weighs 363 grams. The pleural surface of the lung is brown-tan to gray-tan and anthracotic. The pleura has been inked. Within the upper lobe there is a circumscribed gray-brown anthracotic mass that measures 2.0 x 2.0 x 1.2 cm that is within 0.1 cm of the pleural margin and 7.2 cm from the bronchial margin. It is located near the fissure between the upper and lower lobes. The lung in the upper, middle and lower lobes is brown-tan and spongy. There are no other lesions identified grossly. Within the peribronchial soft tissue, there is a gray-tan nodule measuring 0.5 x 0.5 x 0.4 cm, possible lymph node. Received with the specimen are three cassettes, one green, one yellow, one blue labeled 'representative sections are submitted in cassettes labeled as follows: sections from the mass in blocks 1 through 4; bronchiovascular margin in block 5; representative sections from the upper lobe in block 6; middle lobe block 7; lower lobe block 8; possible lymph node bisected in block 9.
- G. The seventh container G is received in formalin labeled with the patient's name 'level 4 lymph node.' The specimen consists of a portion of fibroadipose tissue 3.5 x 3.0 x 1.0 cm. Sectioning reveals eleven possible lymph nodes that measure from 0.3 to 0.9 cm. The lymph nodes are entirely submitted in cassettes as follows: six probable nodes block 1; two probable nodes each bisected in block 2; one probable node bisected in block 3; two probable nodes each bisected in block 4.

Source: NCI Genomic Data Commons file 6ba65976-d9e4-45b0-ac58-92132add80df (TCGA-55-A48Z.74C5526C-5300-4AEA-B2BB-1B78F9B536D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).